Somatic mutation profile of tumor specimen SM-JU33E (aliquot 7316UP-553) from CPTAC case C266664, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS.
Specimen SM-JU33E: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Cerebrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 766adf74-f3ad-49e4-af7a-5283219063c2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105287 (Blood Derived Normal), aliquot 7316UP-393-1105287; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4d154704-9338-446f-9e66-622e65806804

The open-access MAF lists 1,213 somatic variants for this specimen: 850 protein-altering or splice-affecting, 236 silent, 127 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 705, Silent 236, Nonsense Mutation 65, Intron 54, 5'UTR 28, Frame Shift Del 28, 3'UTR 19, Splice Site 17, RNA 15, Splice Region 13, Frame Shift Ins 13, 5'Flank 9.

Variants (750 of 1,213; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3810T>A p.C1270* | Nonsense Mutation (SNP) | VAF 72/134 reads (54%) | catalogued as rs863225347, CM000125, CX995213, COSV57342456, COSV57383570; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GNAS | c.679C>A p.Q227K | Missense Mutation (SNP) | VAF 287/758 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs797045203, CM139760, COSV55671915, COSV55675820, COSV55678737; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.830G>T p.C277F | Missense Mutation (SNP) | VAF 304/539 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs763098116, CM078491, COSV52693726, COSV52826087, COSV53107923; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCA9 | c.3857G>C p.S1286T | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV100383745; called by muse, mutect2, varscan2
- ACHE | c.703G>T p.A235S | Missense Mutation (SNP) | VAF 125/341 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53814894; called by muse, mutect2, varscan2
- ADCY8 | c.1639G>T p.G547W | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53915654; called by muse, mutect2
- AGBL3 | c.205C>A p.L69I | Missense Mutation (SNP) | VAF 32/249 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV51954764; called by muse, mutect2, varscan2
- ALOXE3 | c.1612C>A p.Q538K | Missense Mutation (SNP) | VAF 300/567 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.038); catalogued as rs372027737; called by muse, mutect2, varscan2
- AMBN | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 56/161 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.103); catalogued as rs372201499; called by muse, mutect2, varscan2
- AMER3 | c.2275C>A p.P759T | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.284); catalogued as rs1300776456; called by muse, mutect2, varscan2
- ANGPT1 | c.1473G>A p.M491I | Missense Mutation (SNP) | VAF 68/222 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as COSV52449117; called by muse, mutect2, varscan2
- APAF1 | c.2834G>T p.R945L (on ENST00000551964 / NM_181861.2; = p.R891L on NM_001160.3) | Missense Mutation (SNP) | VAF 72/193 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs146420669; called by muse, mutect2, varscan2
- AR | c.706G>A p.A236T | Missense Mutation (SNP) | VAF 151/248 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1305696138; called by muse, mutect2, varscan2
- ARMC5 | c.353G>T p.S118I | Missense Mutation (SNP) | VAF 159/334 reads (48%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs1182126474, COSV99192819; called by muse, mutect2, varscan2
- ASCC3 | c.6275G>T p.G2092V | Missense Mutation (SNP) | VAF 99/229 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV100976164; called by muse, mutect2, varscan2
- ASTN2 | c.964C>A p.L322M | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.141); catalogued as COSV100528087; called by muse, mutect2, varscan2
- ATP2A2 | c.2030G>A p.R677Q | Missense Mutation (SNP) | VAF 120/251 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57875265, COSV57876016; called by muse, mutect2, varscan2
- ATXN1 | c.837C>G p.H279Q | Missense Mutation (SNP) | VAF 50/125 reads (40%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.462); catalogued as COSV55207534; called by muse, mutect2, varscan2
- AXDND1 | c.259A>T p.K87* | Nonsense Mutation (SNP) | VAF 21/105 reads (20%) | catalogued as COSV62641362; called by muse, mutect2
- B4GALT1 | c.289G>T p.G97C | Missense Mutation (SNP) | VAF 53/106 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as rs1177565118, COSV65709015; called by muse, mutect2, varscan2
- BCL6 | c.2075G>T p.R692L | Missense Mutation (SNP) | VAF 64/168 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV51656145; called by muse, mutect2, varscan2
- BIN1 | c.1397G>C p.G466A (on ENST00000316724 / NM_001320642.1; = p.G327A on NM_004305.4) | Missense Mutation (SNP) | VAF 166/564 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.011); catalogued as rs762512900; called by muse, mutect2, varscan2
- BPIFB4 | c.1101C>G p.S367R | Missense Mutation (SNP) | VAF 27/225 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1376041019; called by muse, mutect2, varscan2
- BRINP1 | c.2005C>A p.L669M | Missense Mutation (SNP) | VAF 43/204 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.24); catalogued as COSV56302494, COSV56307679; called by muse, mutect2, varscan2
- BTBD11 | c.3139G>A p.E1047K (on ENST00000280758 / NM_001018072.2; = p.E584K on NM_001017523.2) | Missense Mutation (SNP) | VAF 38/244 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as rs34000924; called by muse, varscan2
- C1orf87 | c.657C>A p.S219R | Missense Mutation (SNP) | VAF 113/350 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as rs750065570; called by muse, mutect2, varscan2
- CACNA2D1 | c.1590G>C p.K530N | Missense Mutation (SNP) | VAF 83/221 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); catalogued as COSV62385745; called by muse, mutect2, varscan2
- CACNA2D1 | c.772G>T p.V258L | Missense Mutation (SNP) | VAF 19/141 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.068); catalogued as COSV62371428; called by muse, mutect2, varscan2
- CAMKK1 | c.1141G>T p.E381* | Nonsense Mutation (SNP) | VAF 29/219 reads (13%) | catalogued as COSV50126407; called by muse, mutect2, varscan2
- CCDC168 | c.14264C>A p.P4755Q | Missense Mutation (SNP) | VAF 69/156 reads (44%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.999); catalogued as COSV59423319; called by muse, mutect2, varscan2
- CCDC171 | c.2443A>C p.K815Q | Missense Mutation (SNP) | VAF 182/421 reads (43%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs756614235; called by muse, mutect2, varscan2
- CD6 | c.1234C>T p.L412F | Missense Mutation (SNP) | VAF 41/241 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.891); catalogued as rs371896389; called by muse, mutect2, varscan2
- CDH23 | c.3016G>T p.E1006* | Nonsense Mutation (SNP) | VAF 73/205 reads (36%) | catalogued as CM118623; called by muse, mutect2, varscan2
- CDK5RAP2 | c.1711C>A p.L571M | Missense Mutation (SNP) | VAF 69/363 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100575746; called by muse, mutect2, varscan2
- CEBPB | c.263del p.P88Rfs*53 | Frame Shift Del (DEL) | VAF 40/160 reads (25%) | catalogued as rs1213951106; called by mutect2, pindel, varscan2
- CFAP61 | c.892C>T p.Q298* | Nonsense Mutation (SNP) | VAF 33/158 reads (21%) | catalogued as COSV55621866; called by muse, mutect2, varscan2
- CFAP69 | c.1533G>T p.M511I | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV60188600; called by muse, mutect2, varscan2
- CHCHD1 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 31/149 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.452); catalogued as rs756273254; called by muse, mutect2, varscan2
- CHGB | c.650C>A p.S217* | Nonsense Mutation (SNP) | VAF 76/200 reads (38%) | catalogued as rs560272361, COSV66760876; called by muse, mutect2, varscan2
- CHRM3 | c.905G>T p.R302L | Missense Mutation (SNP) | VAF 72/176 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.112); catalogued as rs202097685, COSV55093350, COSV99697259; called by muse, varscan2
- CNTN6 | c.1510G>A p.V504I | Missense Mutation (SNP) | VAF 61/122 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs368850185, COSV63162057; called by muse, mutect2, varscan2
- CNTNAP5 | c.1472G>T p.G491V | Missense Mutation (SNP) | VAF 46/137 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70502012; called by muse, mutect2, varscan2
- COL11A1 | c.4159G>T p.G1387C | Missense Mutation (SNP) | VAF 133/396 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV100615438; called by muse, mutect2, varscan2
- COL19A1 | c.490C>A p.R164S | Missense Mutation (SNP) | VAF 102/259 reads (39%) | SIFT tolerated (0.5); PolyPhen benign (0.247); catalogued as COSV100505503, COSV59572208; called by muse, mutect2, varscan2
- COL22A1 | c.3856G>T p.A1286S | Missense Mutation (SNP) | VAF 87/327 reads (27%) | SIFT tolerated (0.5); PolyPhen benign (0.062); catalogued as COSV57335844; called by muse, mutect2, varscan2
- COL6A5 | c.1160A>G p.Y387C | Missense Mutation (SNP) | VAF 33/224 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1339825242; called by muse, mutect2, varscan2
- COL9A3 | c.343G>T p.G115W | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59654062; called by muse, mutect2, varscan2
- CPED1 | c.339G>T p.Q113H | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.224); catalogued as COSV100119808; called by muse, mutect2, varscan2
- CSMD1 | c.3002C>A p.T1001N (on ENST00000520002; = p.T1000N on NM_033225.6) | Missense Mutation (SNP) | VAF 187/667 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59294813; called by muse, mutect2, varscan2
- CTU1 | c.196G>A p.V66M | Missense Mutation (SNP) | VAF 42/230 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1396291989; called by muse, mutect2, varscan2
- CUX2 | c.3901G>C p.E1301Q | Missense Mutation (SNP) | VAF 43/230 reads (19%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.915); catalogued as COSV55627940, COSV55628772; called by muse, mutect2, varscan2
- CXorf66 | c.331C>A p.P111T | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.316); catalogued as COSV100983798; called by muse, mutect2, varscan2
- DIRAS3 | c.442G>A p.V148M | Missense Mutation (SNP) | VAF 21/162 reads (13%) | SIFT tolerated (0.7); PolyPhen benign (0.172); catalogued as rs761694570; called by muse, mutect2, varscan2
- DLGAP1 | c.542G>A p.R181H | Missense Mutation (SNP) | VAF 42/118 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs752354203; called by muse, mutect2, varscan2
- DMBT1 | c.1448C>T p.A483V | Missense Mutation (SNP) | VAF 36/226 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs758442204; called by muse, mutect2, varscan2
- DMXL1 | c.8329C>T p.Q2777* | Nonsense Mutation (SNP) | VAF 68/166 reads (41%) | catalogued as COSV100224014, COSV100225269; called by muse, mutect2, varscan2
- DNAH7 | c.5764-1G>T p.X1922_splice | Splice Site (SNP) | VAF 42/146 reads (29%) | catalogued as COSV56751522; called by muse, mutect2
- DNAJB4 | c.715G>T p.D239Y | Missense Mutation (SNP) | VAF 67/173 reads (39%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1352636432; called by muse, mutect2, varscan2
- DYSF | c.896G>C p.G299A | Missense Mutation (SNP) | VAF 133/494 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM053212, COSV50483645; called by muse, mutect2, varscan2
- EDIL3 | c.170C>A p.P57H | Missense Mutation (SNP) | VAF 74/219 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV99676277; called by muse, mutect2, varscan2
- EFR3B | c.1181G>C p.R394P | Missense Mutation (SNP) | VAF 57/195 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV104391905; called by muse, mutect2, varscan2
- EML3 | c.1978G>T p.G660W | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99604182; called by muse, mutect2, varscan2
- EPO | c.367G>C p.D123H | Missense Mutation (SNP) | VAF 35/186 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs773297902; called by muse, mutect2, varscan2
- ERICH3 | c.4034G>T p.G1345V | Missense Mutation (SNP) | VAF 139/278 reads (50%) | SIFT tolerated (0.23); PolyPhen benign (0.082); catalogued as COSV58605596; called by muse, mutect2, varscan2
- ETS2 | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 101/414 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.21); catalogued as rs1411415689; called by muse, mutect2, varscan2
- EVX1 | c.903C>A p.S301R | Missense Mutation (SNP) | VAF 147/329 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.115); catalogued as COSV99764062; called by muse, mutect2, varscan2
- EZHIP | c.169G>T p.G57C | Missense Mutation (SNP) | VAF 114/171 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV100539677; called by muse, mutect2, varscan2
- F5 | c.4375G>C p.D1459H | Missense Mutation (SNP) | VAF 71/387 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV63123687, COSV63129999; called by muse, mutect2, varscan2
- F9 | c.1070del p.G357Efs*11 | Frame Shift Del (DEL) | VAF 72/136 reads (53%) | catalogued as rs1198183173, CM094094, CM940636, CM990576; called by mutect2, pindel, varscan2
- FABP1 | c.226G>A p.G76R | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99860851; called by muse, mutect2
- FAM135B | c.712C>T p.H238Y | Missense Mutation (SNP) | VAF 74/205 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs777900338, COSV52730648; called by muse, mutect2, varscan2
- FAM151B | c.485C>T p.T162M | Missense Mutation (SNP) | VAF 60/264 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs1304437732; called by muse, mutect2
- FAM47C | c.2288G>T p.R763L | Missense Mutation (SNP) | VAF 185/308 reads (60%) | SIFT tolerated (0.65); PolyPhen benign (0.006); catalogued as COSV100792410; called by muse, mutect2, varscan2
- FBN3 | c.6796_6810del p.G2266_N2270del | In Frame Del (DEL) | VAF 16/53 reads (30%) | catalogued as rs767570831; called by mutect2, varscan2
- FBXL7 | c.449del p.D150Afs*10 | Frame Shift Del (DEL) | VAF 56/544 reads (10%) | catalogued as COSV61647765; called by mutect2, varscan2
- FBXO40 | c.873G>T p.Q291H | Missense Mutation (SNP) | VAF 76/167 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV57524332; called by muse, mutect2, varscan2
- FYB1 | c.1024C>A p.P342T | Missense Mutation (SNP) | VAF 153/350 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV60952116; called by muse, mutect2, varscan2
- GAD2 | c.1747C>A p.Q583K | Missense Mutation (SNP) | VAF 48/174 reads (28%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs1243932259, COSV99393155; called by muse, mutect2, varscan2
- GBA3 | c.1237G>C p.V413L | Missense Mutation (SNP) | VAF 96/246 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV72438551; called by muse, mutect2, varscan2
- GBP3 | c.608C>A p.S203Y | Missense Mutation (SNP) | VAF 50/266 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1334251131; called by muse, mutect2, varscan2
- GDPD4 | c.1273G>A p.V425I | Missense Mutation (SNP) | VAF 54/147 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1034560793, COSV60016915, COSV60018216; called by muse, mutect2, varscan2
- GHR | c.322G>T p.G108W | Missense Mutation (SNP) | VAF 80/253 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100050195; called by muse, mutect2, varscan2
- GRM8 | c.1946C>A p.S649Y | Missense Mutation (SNP) | VAF 74/238 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as COSV58808223; called by muse, mutect2, varscan2
- GUCY2D | c.1318G>A p.G440R | Missense Mutation (SNP) | VAF 168/280 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs750895890; called by muse, mutect2, varscan2
- GYS2 | c.1425G>A p.V475= | Splice Region (SNP) | VAF 46/314 reads (15%) | catalogued as COSV53925751; called by muse, mutect2, varscan2
- HEPHL1 | c.1399G>C p.D467H | Missense Mutation (SNP) | VAF 86/224 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59890126; called by muse, mutect2, varscan2
- HERC1 | c.14123G>C p.W4708S | Missense Mutation (SNP) | VAF 87/147 reads (59%) | SIFT tolerated (0.95); PolyPhen probably damaging (0.998); catalogued as COSV71250596; called by muse, mutect2, varscan2
- HS6ST3 | c.1121C>G p.S374C | Missense Mutation (SNP) | VAF 77/185 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as rs141432230; called by muse, mutect2, varscan2
- HSPG2 | c.10855A>C p.S3619R | Missense Mutation (SNP) | VAF 221/568 reads (39%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.98); catalogued as COSV65933030; called by muse, mutect2, varscan2
- IGLV11-55 | c.67C>A p.L23M | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV101135393; called by muse, mutect2, varscan2
- IGSF8 | c.1555G>T p.V519L | Missense Mutation (SNP) | VAF 81/253 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.23); catalogued as COSV58758476; called by muse, mutect2, varscan2
- IL21R | c.239C>T p.T80I | Missense Mutation (SNP) | VAF 203/434 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.078); catalogued as rs371591899; called by muse, mutect2, varscan2
- INPP5D | c.2615G>T p.R872L (on ENST00000445964 / NM_001017915.3; = p.R871L on NM_005541.5) | Missense Mutation (SNP) | VAF 89/333 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.283); catalogued as COSV64036256; called by muse, mutect2, varscan2
- IPO7 | c.374G>T p.R125L | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.131); catalogued as rs772562320, COSV65686634; called by muse, mutect2, varscan2
- ITGA8 | c.589C>A p.Q197K | Missense Mutation (SNP) | VAF 57/211 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1381764651; called by muse, mutect2, varscan2
- KALRN | c.4553C>T p.T1518M | Missense Mutation (SNP) | VAF 54/124 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as rs780998165, COSV53758713; called by muse, mutect2, varscan2
- KCNE4 | c.300C>G p.F100L | Missense Mutation (SNP) | VAF 102/485 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1427983334; called by muse, mutect2, varscan2
- KCNG4 | c.1264G>C p.G422R | Missense Mutation (SNP) | VAF 61/119 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100377056; called by muse, mutect2, varscan2
- KCNT1 | c.3010G>T p.G1004C (on ENST00000488444; = p.G1023C on NM_020822.3) | Missense Mutation (SNP) | VAF 37/168 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV104375601; called by muse, mutect2, varscan2
- KCTD4 | c.46G>A p.G16R | Missense Mutation (SNP) | VAF 52/168 reads (31%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.003); catalogued as COSV100476709; called by muse, mutect2
- KHDC1 | c.29G>T p.R10L | Missense Mutation (SNP) | VAF 70/150 reads (47%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.015); catalogued as rs1562263204; called by muse, mutect2, varscan2
- KIAA1109 | c.9407C>A p.P3136H | Missense Mutation (SNP) | VAF 67/243 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV52673100; called by muse, varscan2
- KLF7 | c.544G>C p.A182P | Missense Mutation (SNP) | VAF 58/184 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.327); catalogued as COSV100519073; called by muse, mutect2, varscan2
- KLHL29 | c.416G>A p.S139N | Missense Mutation (SNP) | VAF 85/297 reads (29%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.003); catalogued as rs1173388681; called by muse, mutect2, varscan2
- KNDC1 | c.2272C>T p.R758C | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1359217204; called by muse, mutect2, varscan2
- KRT31 | c.668G>C p.R223P | Missense Mutation (SNP) | VAF 63/247 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.384); catalogued as COSV104381206; called by muse, mutect2, varscan2
- KRTAP19-1 | c.230G>T p.R77L | Missense Mutation (SNP) | VAF 96/305 reads (31%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.21); catalogued as COSV66860928, COSV66861078; called by muse, mutect2, varscan2
- KRTAP22-2 | c.124A>G p.R42G | Missense Mutation (SNP) | VAF 44/116 reads (38%) | PolyPhen benign (0); catalogued as rs1388057362; called by muse, mutect2, varscan2
- KRTAP5-11 | c.224G>T p.G75V | Missense Mutation (SNP) | VAF 171/425 reads (40%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.014); catalogued as COSV100651805; called by muse, mutect2, varscan2
- KRTAP6-3 | c.45C>A p.N15K | Missense Mutation (SNP) | VAF 56/172 reads (33%) | PolyPhen probably damaging (0.909); catalogued as COSV66963409; called by muse, mutect2
- KYAT3 | c.1093A>G p.I365V | Missense Mutation (SNP) | VAF 46/114 reads (40%) | SIFT tolerated (0.72); PolyPhen benign (0.006); catalogued as rs769215372; called by muse, mutect2, varscan2
- LINGO4 | c.653G>T p.R218M | Missense Mutation (SNP) | VAF 90/210 reads (43%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.658); catalogued as COSV59093192; called by muse, mutect2, varscan2
- LMO4 | c.65G>T p.R22L | Missense Mutation (SNP) | VAF 106/305 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV100983997; called by muse, mutect2, varscan2
- LPP | c.698A>G p.H233R | Missense Mutation (SNP) | VAF 182/400 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.03); catalogued as rs762236261; called by muse, mutect2, varscan2
- LRRC7 | c.2791C>A p.P931T (on ENST00000651989 / NM_001370785.2; = p.P898T on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 141/285 reads (49%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.091); catalogued as COSV99224356; called by muse, mutect2, varscan2
- MAP2 | c.3886C>G p.Q1296E | Missense Mutation (SNP) | VAF 49/157 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52296184; called by muse, mutect2, varscan2
- MAPK8IP2 | c.1829G>T p.R610L | Missense Mutation (SNP) | VAF 82/263 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99151156; called by muse, mutect2, varscan2
- MARK1 | c.1940G>A p.G647E | Missense Mutation (SNP) | VAF 132/291 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.065); catalogued as rs1165050058; called by muse, mutect2, varscan2
- MBTPS1 | c.928G>T p.G310C | Missense Mutation (SNP) | VAF 83/181 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58570544; called by muse, mutect2, varscan2
- MEGF8 | c.8170G>A p.A2724T (on ENST00000251268 / NM_001271938.2; = p.A2657T on NM_001410.3) | Missense Mutation (SNP) | VAF 67/240 reads (28%) | SIFT tolerated (0.61); PolyPhen benign (0.006); catalogued as rs530619835, COSV52104254; called by muse, mutect2, varscan2
- MGA | c.4031G>T p.W1344L | Missense Mutation (SNP) | VAF 53/114 reads (46%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.994); catalogued as COSV54953317; called by muse, mutect2, varscan2
- MMP3 | c.176C>A p.P59H | Missense Mutation (SNP) | VAF 35/197 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0.057); catalogued as COSV100243024; called by muse, mutect2, varscan2
- MPIG6B | c.157T>A p.C53S | Missense Mutation (SNP) | VAF 65/117 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1400142656, COSV65390338; called by muse, mutect2, varscan2
- MROH2B | c.2075G>T p.G692V | Missense Mutation (SNP) | VAF 70/173 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV68189770; called by muse, mutect2, varscan2
- MSH4 | c.2161A>G p.T721A | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.591); catalogued as rs762051663; called by muse, mutect2, varscan2
- MTTP | c.1703C>T p.P568L | Missense Mutation (SNP) | VAF 108/324 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs748681503, COSV55507564, COSV99644913; called by muse, mutect2, varscan2
- MTUS2 | c.1588C>A p.L530I | Missense Mutation (SNP) | VAF 54/114 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.072); catalogued as COSV101462271; called by muse, mutect2, varscan2
- MUC16 | c.41503G>T p.V13835F | Missense Mutation (SNP) | VAF 73/180 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.946); catalogued as rs781428326; called by muse, mutect2, varscan2
- MUC17 | c.3914C>G p.T1305S | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs763406863; called by muse, varscan2
- MUC17 | c.11123G>A p.S3708N | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.971); catalogued as COSV60294101; called by muse, mutect2, varscan2
- MUC22 | c.304G>T p.G102W | Missense Mutation (SNP) | VAF 94/147 reads (64%) | SIFT deleterious, low confidence (0.02); catalogued as rs1469259269; called by muse, mutect2, varscan2
- MUC5B | c.10816G>A p.G3606R | Missense Mutation (SNP) | VAF 77/363 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.026); catalogued as rs372672550; called by muse, mutect2, varscan2
- MYBL2 | c.1777G>T p.E593* | Nonsense Mutation (SNP) | VAF 50/194 reads (26%) | catalogued as COSV53829661; called by muse, mutect2, varscan2
- MYH1 | c.5422G>T p.A1808S | Missense Mutation (SNP) | VAF 158/300 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.777); catalogued as COSV56857151; called by muse, mutect2, varscan2
- NAV3 | c.772G>C p.G258R | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.107); catalogued as COSV99888513; called by muse, mutect2, varscan2
- NBEAL1 | c.961C>T p.R321* | Nonsense Mutation (SNP) | VAF 32/100 reads (32%) | catalogued as rs773758454; called by muse, mutect2
- NCKAP5L | c.1421C>T p.P474L | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.296); catalogued as rs774089943; called by muse, mutect2
- NEXMIF | c.952C>G p.Q318E | Missense Mutation (SNP) | VAF 65/108 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV50023282; called by muse, mutect2, varscan2
- NLGN1 | c.256G>T p.A86S | Missense Mutation (SNP) | VAF 141/255 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64349101; called by muse, mutect2, varscan2
- NLGN4X | c.2218G>T p.D740Y | Missense Mutation (SNP) | VAF 154/260 reads (59%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.333); catalogued as COSV52012012; called by muse, mutect2, varscan2
- NOTCH2 | c.2440A>G p.I814V | Missense Mutation (SNP) | VAF 101/274 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782757612; called by muse, mutect2, varscan2
- NOTCH4 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 44/69 reads (64%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.513); catalogued as rs1304701623, COSV66681126; called by muse, mutect2
- NPBWR2 | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 60/160 reads (38%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs370307704; called by muse, mutect2, varscan2
- NPY2R | c.625G>A p.G209S | Missense Mutation (SNP) | VAF 117/634 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.022); catalogued as COSV61527622; called by muse, mutect2, varscan2
- NTRK3 | c.1987A>T p.I663F | Missense Mutation (SNP) | VAF 59/326 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62296630; called by muse, mutect2, varscan2
- OR10G3 | c.831del p.T278Rfs*19 | Frame Shift Del (DEL) | VAF 38/164 reads (23%) | catalogued as COSV100336118; called by mutect2, pindel, varscan2
- OR4C16 | c.484C>A p.L162M | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV58942770; called by muse, mutect2, varscan2
- OR4K1 | c.24G>C p.M8I | Missense Mutation (SNP) | VAF 40/156 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV99579397; called by muse, mutect2
- OR8K3 | c.72G>T p.Q24H | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.933); catalogued as COSV57131466; called by muse, mutect2, varscan2
- OR9G1 | c.707C>A p.A236D | Missense Mutation (SNP) | VAF 21/205 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56448909; called by muse, mutect2, varscan2
- OSBPL5 | c.2467C>T p.L823F | Missense Mutation (SNP) | VAF 60/154 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.24); catalogued as rs1227879264; called by muse, mutect2, varscan2
- PCDHGB1 | c.806G>A p.G269D | Missense Mutation (SNP) | VAF 146/286 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs930490756; called by muse, mutect2, varscan2
- PCNT | c.6889G>A p.A2297T | Missense Mutation (SNP) | VAF 49/185 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.023); catalogued as rs959271732; called by muse, mutect2, varscan2
- PDE1B | c.1290G>T p.E430D | Missense Mutation (SNP) | VAF 57/155 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.12); catalogued as COSV99226348; called by muse, mutect2, varscan2
- PDP1 | c.1064A>G p.D355G | Missense Mutation (SNP) | VAF 172/468 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99892212; called by muse, mutect2, varscan2
- PERM1 | c.1359C>A p.D453E | Missense Mutation (SNP) | VAF 118/408 reads (29%) | SIFT tolerated (0.87); PolyPhen possibly damaging (0.62); catalogued as rs776964907; called by muse, mutect2, varscan2
- PIWIL4 | c.1192G>T p.A398S | Missense Mutation (SNP) | VAF 23/153 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.21); catalogued as COSV54412393; called by muse, mutect2, varscan2
- PKHD1L1 | c.2494G>T p.G832* | Nonsense Mutation (SNP) | VAF 17/71 reads (24%) | catalogued as COSV65749315; called by muse, mutect2, varscan2
- PNPLA6 | c.3112G>T p.E1038* (on ENST00000414982 / NM_001166111.2; = p.E990* on NM_006702.5) | Nonsense Mutation (SNP) | VAF 112/206 reads (54%) | catalogued as COSV99075571; called by muse, mutect2, varscan2
- POLD1 | c.1409G>T p.R470L | Missense Mutation (SNP) | VAF 30/202 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV70956804; called by muse, mutect2, varscan2
- POLE4 | c.16G>A p.A6T | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs1269666375; called by muse, mutect2, varscan2
- PRAMEF4 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 283/392 reads (72%) | SIFT tolerated (0.28); PolyPhen benign (0.033); catalogued as COSV52437958; called by muse, mutect2, varscan2
- PRDM8 | c.650A>T p.Q217L | Missense Mutation (SNP) | VAF 48/282 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.075); catalogued as rs752993100; called by muse, varscan2
- PRDM9 | c.1084G>A p.G362S | Missense Mutation (SNP) | VAF 165/674 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.308); catalogued as rs184753683; called by muse, mutect2, varscan2
- PRSS58 | c.235C>A p.L79M | Missense Mutation (SNP) | VAF 58/168 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); catalogued as COSV73488797; called by muse, mutect2, varscan2
- PTCHD3 | c.596C>A p.A199D | Missense Mutation (SNP) | VAF 49/157 reads (31%) | SIFT tolerated (0.59); PolyPhen benign (0.029); catalogued as COSV71256775; called by muse, mutect2, varscan2
- PTCHD4 | c.2074G>A p.V692I | Missense Mutation (SNP) | VAF 52/285 reads (18%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.642); catalogued as rs528776718, COSV59778280, COSV59779193; called by muse, mutect2, varscan2
- RASGRF2 | c.1914G>T p.Q638H | Missense Mutation (SNP) | VAF 186/516 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV54130199; called by muse, mutect2, varscan2
- RBAK-RBAKDN | c.526G>A p.D176N | Missense Mutation (SNP) | VAF 74/200 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.14); catalogued as COSV101208255; called by muse, mutect2, varscan2
- RNASE3 | c.388G>A p.G130R | Missense Mutation (SNP) | VAF 88/364 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.131); catalogued as rs12147890; called by muse, mutect2
- RNASE3 | c.389G>T p.G130V | Missense Mutation (SNP) | VAF 88/361 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.09); catalogued as COSV58959335; called by muse, mutect2
- ROBO2 | c.216G>T p.E72D | Missense Mutation (SNP) | VAF 168/318 reads (53%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.536); catalogued as COSV59922831; called by muse, mutect2, varscan2
- RP1L1 | c.2965G>T p.G989C | Missense Mutation (SNP) | VAF 216/689 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV101223271; called by muse, mutect2, varscan2
- RRP12 | c.3412C>T p.R1138W | Missense Mutation (SNP) | VAF 37/195 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as rs774617555; called by muse, mutect2
- RUFY2 | c.231del p.L78Cfs*12 | Frame Shift Del (DEL) | VAF 30/86 reads (35%) | catalogued as rs751531309; called by mutect2, varscan2
- SALL4 | c.1757G>T p.R586L | Missense Mutation (SNP) | VAF 197/719 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53854576; called by muse, mutect2, varscan2
- SATL1 | c.350C>A p.S117* (on ENST00000395409; = p.S304* on NM_001012980.2) | Nonsense Mutation (SNP) | VAF 128/202 reads (63%) | catalogued as COSV60577984; called by muse, mutect2, varscan2
- SECTM1 | c.244G>A p.A82T | Missense Mutation (SNP) | VAF 150/655 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.031); catalogued as rs1439174252; called by muse, mutect2, varscan2
- SEMA6D | c.1940G>A p.R647Q (on ENST00000316364 / NM_153618.2; = p.R585Q on NM_020858.2) | Missense Mutation (SNP) | VAF 22/26 reads (85%) | SIFT tolerated (0.35); PolyPhen benign (0.233); catalogued as rs775757768, COSV100317124, COSV99054636; called by muse, varscan2
- SETD1B | c.5059G>T p.G1687C | Missense Mutation (SNP) | VAF 68/182 reads (37%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.98); catalogued as rs553963413; called by muse, mutect2, varscan2
- SF1 | c.1436C>T p.P479L | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.982); catalogued as rs371270819; called by muse, varscan2
- SH3RF3 | c.2210G>T p.R737L | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV100514096; called by muse, mutect2, varscan2
- SIGLEC7 | c.1066G>A p.V356I | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs771941732; called by muse, mutect2, varscan2
- SLC22A25 | c.457A>G p.M153V | Missense Mutation (SNP) | VAF 22/142 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.247); catalogued as rs1272844107; called by muse, mutect2, varscan2
- SLC30A10 | c.1382G>C p.S461T | Missense Mutation (SNP) | VAF 63/151 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as COSV63076390; called by muse, mutect2, varscan2
- SLC35G5 | c.617G>C p.G206A | Missense Mutation (SNP) | VAF 103/346 reads (30%) | SIFT tolerated (0.44); PolyPhen benign (0.081); catalogued as rs764168543; called by muse, mutect2, varscan2
- SLITRK2 | c.313del p.A105Hfs*5 | Frame Shift Del (DEL) | VAF 78/176 reads (44%) | catalogued as COSV59424912; called by mutect2, pindel, varscan2
- SLITRK4 | c.11G>T p.W4L | Missense Mutation (SNP) | VAF 24/39 reads (62%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV100567516; called by muse, mutect2, varscan2
- SNTG1 | c.707T>A p.V236E | Missense Mutation (SNP) | VAF 70/239 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as rs1241317655; called by muse, mutect2, varscan2
- SPAG16 | c.1183G>C p.D395H | Missense Mutation (SNP) | VAF 52/165 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100530410; called by muse, mutect2, varscan2
- SSX3 | c.269G>C p.R90P | Missense Mutation (SNP) | VAF 128/196 reads (65%) | SIFT tolerated (0.46); PolyPhen benign (0.006); catalogued as COSV53643939, COSV53646757; called by muse, mutect2, varscan2
- ST3GAL4 | c.193G>T p.D65Y (on ENST00000392669 / NM_001254758.1; = p.D61Y on NM_006278.3) | Missense Mutation (SNP) | VAF 109/271 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.526); catalogued as COSV57109437; called by muse, mutect2, varscan2
- ST8SIA1 | c.460C>A p.R154S | Missense Mutation (SNP) | VAF 79/225 reads (35%) | SIFT tolerated (0.63); PolyPhen benign (0.174); catalogued as rs565011134; called by muse, mutect2, varscan2
- STK11 | c.443T>C p.F148S | Missense Mutation (SNP) | VAF 107/182 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58829789; called by muse, mutect2, varscan2
- SUGCT | c.589G>A p.V197I | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.69); catalogued as rs1203172280; called by muse, mutect2, varscan2
- SULF2 | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 86/276 reads (31%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.774); catalogued as rs373180984; called by muse, mutect2, varscan2
- SVEP1 | c.3212C>A p.S1071* | Nonsense Mutation (SNP) | VAF 48/172 reads (28%) | catalogued as COSV57029663; called by muse, mutect2, varscan2
- SYT12 | c.765G>C p.E255D | Missense Mutation (SNP) | VAF 75/445 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as rs778042037; called by muse, mutect2, varscan2
- TACO1 | c.652G>T p.V218F | Missense Mutation (SNP) | VAF 77/275 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV51976360; called by muse, mutect2, varscan2
- TBC1D1 | c.3425C>T p.T1142M | Missense Mutation (SNP) | VAF 147/431 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.085); catalogued as rs151143743; called by muse, mutect2, varscan2
- TIAM1 | c.4346G>T p.R1449L | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.468); catalogued as COSV54554620; called by muse, mutect2, varscan2
- TIFAB | c.326G>T p.G109V | Missense Mutation (SNP) | VAF 188/337 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.785); catalogued as COSV72345691; called by muse, mutect2, varscan2
- TLR5 | c.200C>T p.P67L | Missense Mutation (SNP) | VAF 47/89 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV60558213, COSV60560154; called by muse, mutect2, varscan2
- TMEM161A | c.977G>T p.R326L | Missense Mutation (SNP) | VAF 73/156 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV50776683; called by muse, mutect2, varscan2
- TMEM178B | c.585G>T p.W195C | Missense Mutation (SNP) | VAF 87/235 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV73803549; called by muse, mutect2, varscan2
- TMEM179 | c.7C>T p.L3F | Missense Mutation (SNP) | VAF 58/106 reads (55%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.788); catalogued as rs1433425536; called by muse, mutect2, varscan2
- TMPRSS11A | c.268G>T p.E90* | Nonsense Mutation (SNP) | VAF 19/82 reads (23%) | catalogued as COSV100602790; called by muse, mutect2, varscan2
- TRBV20-1 | c.146G>T p.W49L | Missense Mutation (SNP) | VAF 87/287 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760783607; called by muse, mutect2, varscan2
- TRIM65 | c.188A>G p.N63S | Missense Mutation (SNP) | VAF 102/452 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as rs1256281792, COSV99485496; called by muse, mutect2, varscan2
- TRIM9 | c.427C>T p.R143C | Missense Mutation (SNP) | VAF 112/244 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs762640179, COSV53612436; called by muse, mutect2, varscan2
- TRPV5 | c.2068C>G p.R690G | Missense Mutation (SNP) | VAF 152/444 reads (34%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.989); catalogued as COSV99520590; called by muse, mutect2, varscan2
- TTC29 | c.568C>G p.L190V | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV100283640; called by muse, varscan2
- TTLL5 | c.2990C>T p.S997L | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs759872181, COSV100089536; called by muse, mutect2, varscan2
- TWIST1 | c.355C>A p.Q119K | Missense Mutation (SNP) | VAF 38/224 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as CD013661, CD982422, CM060093; called by muse, varscan2
- UNC45A | c.2350A>G p.M784V | Missense Mutation (SNP) | VAF 107/188 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV67793621; called by muse, mutect2, varscan2
- UNC5D | c.2752C>A p.L918M | Missense Mutation (SNP) | VAF 158/543 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54782165; called by muse, mutect2, varscan2
- VGLL3 | c.489G>T p.L163F | Missense Mutation (SNP) | VAF 63/131 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs962129357; called by muse, mutect2, varscan2
- VIRMA | c.2251G>T p.G751C | Missense Mutation (SNP) | VAF 76/228 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.735); catalogued as COSV99889412; called by muse, mutect2, varscan2
- WBP1 | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 73/188 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs776821607; called by muse, mutect2, varscan2
- WDR90 | c.1285G>T p.A429S | Missense Mutation (SNP) | VAF 92/212 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.02); catalogued as COSV53471855; called by muse, varscan2
- WNK4 | c.2908G>C p.A970P | Missense Mutation (SNP) | VAF 40/243 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.203); catalogued as rs372187677; called by muse, mutect2, varscan2
- WNT10A | c.647C>A p.P216H | Missense Mutation (SNP) | VAF 99/285 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV51463831; called by muse, mutect2, varscan2
- XIRP2 | c.8311G>C p.E2771Q (on ENST00000628543; = p.E2946Q on NM_152381.6) | Missense Mutation (SNP) | VAF 66/221 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.291); catalogued as COSV99737015; called by muse, mutect2, varscan2
- ZEB2 | c.1027del p.R343Efs*2 | Frame Shift Del (DEL) | VAF 11/121 reads (9%) | catalogued as CM031406, COSV100356564; called by mutect2, pindel, varscan2
- ZNF134 | c.471G>T p.R157S | Missense Mutation (SNP) | VAF 30/224 reads (13%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV68696231; called by muse, mutect2, varscan2
- ZNF225 | c.15+1G>T p.X5_splice | Splice Site (SNP) | VAF 32/119 reads (27%) | catalogued as COSV53471936; called by muse, mutect2, varscan2
- ZNF536 | c.2168C>A p.S723* | Nonsense Mutation (SNP) | VAF 11/64 reads (17%) | catalogued as COSV100835538, COSV62817472; called by muse, varscan2
- ZNF684 | c.848G>T p.S283I | Missense Mutation (SNP) | VAF 22/158 reads (14%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.67); catalogued as rs1323868688; called by muse, mutect2, varscan2
- ZNF761 | c.2190G>T p.K730N | Missense Mutation (SNP) | VAF 159/320 reads (50%) | SIFT tolerated (0.76); PolyPhen benign (0.037); catalogued as COSV100483334; called by muse, mutect2, varscan2
- ZNF804B | c.2438A>T p.N813I | Missense Mutation (SNP) | VAF 39/127 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.012); catalogued as COSV60863770; called by muse, mutect2, varscan2
- ZP3 | c.580G>A p.D194N (on ENST00000394857 / NM_001110354.2; = p.D143N on NM_007155.6) | Missense Mutation (SNP) | VAF 39/179 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs753936084; called by muse, mutect2, varscan2
- AASDH | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 46/144 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.766); called by muse, varscan2
- ABCA13 | c.14034C>A p.D4678E | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ABCC8 | c.2872G>T p.A958S | Missense Mutation (SNP) | VAF 170/446 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ABCG1 | c.1888C>T p.H630Y | Missense Mutation (SNP) | VAF 102/422 reads (24%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.487); called by muse, mutect2, varscan2
- ABI3 | c.800C>A p.P267Q | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.503); called by muse, mutect2
- ACTA2 | c.493G>T p.V165F | Missense Mutation (SNP) | VAF 93/399 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAM9 | c.1603G>T p.A535S | Missense Mutation (SNP) | VAF 69/325 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- ADAMTS12 | c.3049C>T p.P1017S | Missense Mutation (SNP) | VAF 34/548 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, mutect2
- ADAMTSL3 | c.2221dup p.E741Gfs*6 | Frame Shift Ins (INS) | VAF 68/172 reads (40%) | called by pindel, varscan2
- ADCY3 | c.954C>G p.V318= | Splice Region (SNP) | VAF 48/141 reads (34%) | called by muse, mutect2, varscan2
- ADGRB1 | c.1903G>T p.V635F | Missense Mutation (SNP) | VAF 28/289 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); called by muse, mutect2
- ADGRB1 | c.2705G>T p.G902V | Missense Mutation (SNP) | VAF 39/141 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- ADGRL2 | c.2555G>T p.W852L (on ENST00000370717 / NM_001366005.1; = p.W839L on NM_012302.4) | Missense Mutation (SNP) | VAF 55/431 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- ADGRL4 | c.22+7G>T | Splice Region (SNP) | VAF 28/123 reads (23%) | called by muse, mutect2, varscan2
- ADH1C | c.1075G>T p.G359* | Nonsense Mutation (SNP) | VAF 38/123 reads (31%) | called by muse, mutect2, varscan2
- AFF2 | c.2564A>C p.H855P | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- AFF3 | c.679G>T p.V227F | Missense Mutation (SNP) | VAF 68/198 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- AGFG1 | c.890G>A p.G297E | Missense Mutation (SNP) | VAF 108/379 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- AHCYL2 | c.178C>G p.P60A | Missense Mutation (SNP) | VAF 59/227 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- AJAP1 | c.1009T>A p.S337T | Missense Mutation (SNP) | VAF 144/608 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- AKR1C2 | c.595C>A p.Q199K | Missense Mutation (SNP) | VAF 45/201 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- ALDH8A1 | c.1311G>C p.K437N | Missense Mutation (SNP) | VAF 165/358 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- ALPL | c.591G>T p.L197F | Missense Mutation (SNP) | VAF 157/304 reads (52%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- AMBP | c.227A>T p.E76V | Missense Mutation (SNP) | VAF 64/231 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- AMOTL2 | c.2068C>G p.R690G | Missense Mutation (SNP) | VAF 69/409 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AMY2B | c.413G>A p.S138N | Missense Mutation (SNP) | VAF 134/881 reads (15%) | SIFT tolerated (0.86); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD30A | c.146G>C p.G49A | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- ANKRD30A | c.4075A>T p.R1359W (on ENST00000611781; = p.R1303W on NM_052997.2) | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- ANKRD30BL | c.678A>C p.P226= | Splice Region (SNP) | VAF 32/110 reads (29%) | called by muse, mutect2, varscan2
- ANKRD60 | c.497G>T p.C166F | Missense Mutation (SNP) | VAF 38/137 reads (28%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.695); called by muse, mutect2, varscan2
- AP1B1 | c.2264C>G p.A755G | Missense Mutation (SNP) | VAF 55/180 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- APBB2 | c.1378A>C p.T460P (on ENST00000295974 / NM_001166050.2; = p.T461P on NM_004307.2) | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- APLP2 | c.1840A>T p.T614S | Missense Mutation (SNP) | VAF 49/252 reads (19%) | SIFT tolerated (0.9); PolyPhen benign (0); called by muse, mutect2, varscan2
- APLP2 | c.2107G>T p.V703L | Missense Mutation (SNP) | VAF 72/209 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- AQP11 | c.50C>A p.S17* | Nonsense Mutation (SNP) | VAF 29/67 reads (43%) | called by muse, mutect2, varscan2
- ARFIP2 | c.978G>T p.K326N | Missense Mutation (SNP) | VAF 80/188 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ARHGAP23 | c.1916G>T p.R639L | Missense Mutation (SNP) | VAF 55/165 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ARHGAP28 | c.2178A>C p.Q726H (on ENST00000383472 / NM_001366230.1; = p.Q567H on NM_001010000.3) | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- ARID5B | c.976G>T p.V326L | Missense Mutation (SNP) | VAF 92/308 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.545); called by muse, mutect2, varscan2
- ARMC2 | c.567del p.S190Vfs*6 | Frame Shift Del (DEL) | VAF 73/169 reads (43%) | called by mutect2, pindel, varscan2
- ASB7 | c.85A>G p.T29A | Missense Mutation (SNP) | VAF 236/419 reads (56%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ASIC2 | c.595G>T p.G199C | Missense Mutation (SNP) | VAF 26/190 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- ATAD2 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 68/212 reads (32%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP13A4 | c.2304G>A p.M768I | Missense Mutation (SNP) | VAF 135/328 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP6V1B1 | c.1158C>G p.I386M | Missense Mutation (SNP) | VAF 131/501 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- AUTS2 | c.3133A>G p.M1045V | Missense Mutation (SNP) | VAF 67/214 reads (31%) | SIFT tolerated (0.48); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- BACE2 | c.55C>A p.R19S | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- BBOX1 | c.223T>C p.Y75H | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2
- BIRC6 | c.7309G>T p.D2437Y | Missense Mutation (SNP) | VAF 64/260 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- BOD1L1 | c.1478G>T p.R493L | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, varscan2
- BPI | c.552G>T p.W184C (on ENST00000262865; = p.W180C on NM_001725.3) | Missense Mutation (SNP) | VAF 38/150 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- BPTF | c.6508G>T p.G2170* | Nonsense Mutation (SNP) | VAF 39/165 reads (24%) | called by muse, mutect2, varscan2
- BRD1 | c.2646_2649dup p.H884Tfs*9 (on ENST00000216267 / NM_001349940.1; = p.H1015Tfs*9 on NM_001304808.3) | Frame Shift Ins (INS) | VAF 40/265 reads (15%) | called by mutect2, pindel, varscan2
- BRDT | c.445+8A>T | Splice Region (SNP) | VAF 15/74 reads (20%) | called by muse, mutect2, varscan2
- BST1 | c.487T>A p.C163S | Missense Mutation (SNP) | VAF 21/177 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BTG3 | c.21del p.V8Lfs*8 | Frame Shift Del (DEL) | VAF 27/118 reads (23%) | called by mutect2, pindel, varscan2
- C17orf99 | c.163C>A p.P55T | Missense Mutation (SNP) | VAF 197/490 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- C17orf99 | c.164C>G p.P55R | Missense Mutation (SNP) | VAF 196/490 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.426); called by muse, mutect2, varscan2
- C1QC | c.110G>T p.G37V | Missense Mutation (SNP) | VAF 45/254 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C3orf80 | c.110_111insT p.G38Rfs*6 | Frame Shift Ins (INS) | VAF 24/156 reads (15%) | called by mutect2, pindel, varscan2
- C8A | c.1402C>A p.L468M | Missense Mutation (SNP) | VAF 62/254 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- C9 | c.69C>A p.Y23* | Nonsense Mutation (SNP) | VAF 69/385 reads (18%) | called by muse, mutect2, varscan2
- CABS1 | c.1081G>A p.G361R | Missense Mutation (SNP) | VAF 50/185 reads (27%) | SIFT tolerated (0.48); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CACNG5 | c.779C>A p.A260D | Missense Mutation (SNP) | VAF 48/137 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- CALCOCO2 | c.350G>T p.R117L | Missense Mutation (SNP) | VAF 57/196 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- CAMK4 | c.580C>A p.H194N | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- CAMK4 | c.1205_1212del p.K402Rfs*7 | Frame Shift Del (DEL) | VAF 21/49 reads (43%) | called by mutect2, pindel, varscan2
- CASQ2 | c.1077G>C p.E359D | Missense Mutation (SNP) | VAF 48/353 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- CASTOR2 | c.314C>G p.A105G | Missense Mutation (SNP) | VAF 215/628 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- CBX2 | c.74G>T p.G25V | Missense Mutation (SNP) | VAF 128/535 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- CBX4 | c.558_576del p.D187Tfs*19 | Frame Shift Del (DEL) | VAF 23/142 reads (16%) | called by pindel, varscan2
- CCDC105 | c.1252G>T p.G418C | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- CCDC166 | c.53C>A p.A18E | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- CCDC169 | c.429C>G p.I143M | Missense Mutation (SNP) | VAF 35/170 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- CCDC171 | c.2941C>G p.Q981E | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- CCDC180 | c.883G>C p.D295H | Missense Mutation (SNP) | VAF 63/131 reads (48%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.639); called by muse, mutect2, varscan2
- CCDC73 | c.2059C>A p.Q687K | Missense Mutation (SNP) | VAF 56/166 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- CCDC81 | c.917_919dup p.E306_M307insK (on ENST00000445632 / NM_001156474.2; = p.E216_M217insK on NM_021827.4) | In Frame Ins (INS) | VAF 35/148 reads (24%) | called by mutect2, pindel, varscan2
- CCDC96 | c.154G>T p.E52* | Nonsense Mutation (SNP) | VAF 68/232 reads (29%) | called by mutect2, varscan2
- CCL18 | c.53G>T p.C18F | Missense Mutation (SNP) | VAF 73/237 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- CCNE2 | c.575C>A p.S192* | Nonsense Mutation (SNP) | VAF 17/57 reads (30%) | called by muse, mutect2, varscan2
- CD177 | c.1016C>A p.S339Y | Missense Mutation (SNP) | VAF 21/161 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- CD274 | c.36C>A p.Y12* | Nonsense Mutation (SNP) | VAF 65/143 reads (45%) | called by muse, mutect2, varscan2
- CD320 | c.535A>T p.T179S | Missense Mutation (SNP) | VAF 182/402 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- CD38 | c.305C>A p.T102N | Missense Mutation (SNP) | VAF 44/140 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- CDC14C | c.1230C>G p.Y410* (on ENST00000428251; = p.Y303* on NM_152627.3) | Nonsense Mutation (SNP) | VAF 61/449 reads (14%) | called by muse, mutect2, varscan2
- CDH4 | c.707A>G p.D236G | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); called by muse, varscan2
- CDHR2 | c.2356C>A p.Q786K | Missense Mutation (SNP) | VAF 40/64 reads (63%) | SIFT tolerated (0.86); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- CDK11A | c.919A>T p.T307S (on ENST00000378633 / NM_001313896.2; = p.T304S on NM_024011.4) | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); called by mutect2, varscan2
- CDK13 | c.2221del p.E741Kfs*27 | Frame Shift Del (DEL) | VAF 32/89 reads (36%) | called by mutect2, pindel, varscan2
- CDON | c.829A>T p.T277S | Missense Mutation (SNP) | VAF 98/262 reads (37%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- CENPE | c.560-2A>T p.X187_splice | Splice Site (SNP) | VAF 29/86 reads (34%) | called by muse, mutect2, varscan2
- CFAP46 | c.4598T>A p.L1533Q | Missense Mutation (SNP) | VAF 52/138 reads (38%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- CFAP46 | c.1960G>C p.A654P | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CFAP47 | c.1078_1079del p.P360Ffs*13 | Frame Shift Del (DEL) | VAF 21/75 reads (28%) | called by mutect2, pindel, varscan2
- CFAP53 | c.967G>T p.E323* | Nonsense Mutation (SNP) | VAF 67/241 reads (28%) | called by muse, mutect2, varscan2
- CFAP92 | c.359A>C p.E120A | Missense Mutation (SNP) | VAF 30/317 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CGREF1 | c.692C>A p.A231D | Missense Mutation (SNP) | VAF 112/358 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, varscan2
- CHAF1A | c.762G>T p.K254N | Missense Mutation (SNP) | VAF 54/109 reads (50%) | SIFT tolerated (0.38); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- CHAT | c.1082G>T p.W361L | Missense Mutation (SNP) | VAF 47/326 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHAT | c.1438C>A p.P480T | Missense Mutation (SNP) | VAF 87/373 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CHD4 | c.4639G>A p.A1547T (on ENST00000357008 / NM_001363606.2; = p.A1560T on NM_001273.5) | Missense Mutation (SNP) | VAF 38/71 reads (54%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CHD4 | c.3110G>T p.G1037V (on ENST00000357008 / NM_001363606.2; = p.G1050V on NM_001273.5) | Missense Mutation (SNP) | VAF 34/223 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CHD8 | c.2346_2362del p.P783Efs*16 (on ENST00000646647 / NM_001170629.2; = p.P504Efs*16 on NM_020920.4) | Frame Shift Del (DEL) | VAF 65/177 reads (37%) | called by mutect2, pindel, varscan2
- CHD9 | c.8374G>T p.A2792S (on ENST00000398510 / NM_001382353.1; = p.A2776S on NM_025134.7) | Missense Mutation (SNP) | VAF 60/139 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- CHRDL2 | c.1239G>T p.Q413H (on ENST00000376332 / NM_001304415.1; = p.D432Y on NM_015424.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 68/257 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- CHRM1 | c.913C>A p.P305T | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- CHRM4 | c.1056G>T p.E352D | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.72); PolyPhen benign (0.01); called by muse, mutect2
- CMKLR1 | c.631C>A p.P211T (on ENST00000312143 / NM_001142344.2; = p.P209T on NM_004072.3) | Missense Mutation (SNP) | VAF 118/315 reads (37%) | SIFT tolerated (0.56); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CMYA5 | c.6571A>T p.T2191S | Missense Mutation (SNP) | VAF 43/134 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- CMYA5 | c.8510C>T p.P2837L | Missense Mutation (SNP) | VAF 49/177 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- CNGA3 | c.2012G>T p.G671V | Missense Mutation (SNP) | VAF 36/207 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CNGB3 | c.481A>T p.S161C | Missense Mutation (SNP) | VAF 120/317 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- CNTNAP5 | c.630G>T p.K210N | Missense Mutation (SNP) | VAF 130/429 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL12A1 | c.5442del p.K1814Nfs*22 | Frame Shift Del (DEL) | VAF 33/90 reads (37%) | called by mutect2, pindel, varscan2
- COL16A1 | c.1514A>C p.D505A | Missense Mutation (SNP) | VAF 42/251 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- COL16A1 | c.157C>G p.L53V | Missense Mutation (SNP) | VAF 193/273 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- COL2A1 | c.1897G>T p.G633C | Missense Mutation (SNP) | VAF 91/295 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- COL2A1 | c.293-7C>A | Splice Region (SNP) | VAF 43/303 reads (14%) | called by muse, mutect2, varscan2
- COL6A6 | c.2018A>T p.E673V | Missense Mutation (SNP) | VAF 48/316 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- COMMD10 | c.436G>T p.A146S | Missense Mutation (SNP) | VAF 74/160 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- COPS8 | c.150-1G>A p.X50_splice | Splice Site (SNP) | VAF 48/124 reads (39%) | called by muse, mutect2, varscan2
- CPEB2 | c.958C>A p.P320T | Missense Mutation (SNP) | VAF 76/209 reads (36%) | SIFT tolerated, low confidence (0.12); called by muse, mutect2, varscan2
- CRB2 | c.2441dup p.D814Efs*15 | Frame Shift Ins (INS) | VAF 33/197 reads (17%) | called by mutect2, pindel, varscan2
- CREM | c.729G>T p.M243I (on ENST00000429130; = p.M19I on NM_182717.2) | Missense Mutation (SNP) | VAF 94/308 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- CRKL | c.548G>T p.R183I | Missense Mutation (SNP) | VAF 106/368 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- CRTAC1 | c.312C>A p.Y104* | Nonsense Mutation (SNP) | VAF 42/232 reads (18%) | called by muse, mutect2, varscan2
- CRYBA4 | c.509C>A p.S170Y | Missense Mutation (SNP) | VAF 145/525 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- CRYGA | c.10-1G>T p.X4_splice | Splice Site (SNP) | VAF 64/201 reads (32%) | called by muse, mutect2, varscan2
- CSMD3 | c.8660G>T p.S2887I (on ENST00000297405 / NM_001363185.1; = p.S2718I on NM_052900.3) | Missense Mutation (SNP) | VAF 45/367 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- CSN2 | c.*36+1G>T | Splice Site (SNP) | VAF 5/20 reads (25%) | called by muse, mutect2
- CSTA | c.149G>T p.G50V | Missense Mutation (SNP) | VAF 45/212 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CUX1 | c.1493A>T p.Q498L | Missense Mutation (SNP) | VAF 38/194 reads (20%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- DBX2 | c.726del p.N243Ifs*16 | Frame Shift Del (DEL) | VAF 12/31 reads (39%) | called by mutect2, pindel, varscan2
- DCAF17 | c.1031G>C p.W344S | Missense Mutation (SNP) | VAF 98/291 reads (34%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- DCBLD1 | c.906_907del p.D303Qfs*2 | Frame Shift Del (DEL) | VAF 124/385 reads (32%) | called by mutect2, pindel, varscan2
- DCSTAMP | c.848T>A p.F283Y | Missense Mutation (SNP) | VAF 48/258 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- DDR2 | c.1274G>T p.W425L | Missense Mutation (SNP) | VAF 138/471 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- DDX60 | c.3143A>G p.Q1048R | Missense Mutation (SNP) | VAF 25/165 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- DDX60L | c.3217A>T p.K1073* | Nonsense Mutation (SNP) | VAF 23/92 reads (25%) | called by muse, mutect2, varscan2
- DGKZ | c.3339G>T p.Q1113H (on ENST00000454345 / NM_001105540.2; = p.Q925H on NM_003646.4) | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- DHX16 | c.2411A>G p.H804R | Missense Mutation (SNP) | VAF 111/194 reads (57%) | SIFT tolerated (0.18); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- DLEU7 | c.184G>T p.G62W | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- DLG2 | c.2550C>G p.C850W | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- DLGAP3 | c.2443C>T p.Q815* | Nonsense Mutation (SNP) | VAF 99/471 reads (21%) | called by muse, mutect2, varscan2
- DLGAP5 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 52/132 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- DMXL1 | c.2335G>T p.A779S | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAJB11 | c.389G>T p.R130I | Missense Mutation (SNP) | VAF 20/156 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- DNAJC12 | c.298-1G>A p.X100_splice | Splice Site (SNP) | VAF 26/64 reads (41%) | called by muse, mutect2, varscan2
- DNM3 | c.13G>C p.E5Q | Missense Mutation (SNP) | VAF 151/482 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- DOCK4 | c.2342G>T p.R781L | Missense Mutation (SNP) | VAF 40/220 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- DOCK9 | c.5519G>C p.G1840A (on ENST00000376460 / NM_001366676.2; = p.G1841A on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/88 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DOP1B | c.6415G>T p.G2139W | Missense Mutation (SNP) | VAF 84/252 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DOT1L | c.231G>T p.K77N | Missense Mutation (SNP) | VAF 90/221 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DPEP3 | c.488T>C p.L163P | Missense Mutation (SNP) | VAF 63/148 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- DROSHA | c.2149G>T p.E717* | Nonsense Mutation (SNP) | VAF 63/341 reads (18%) | called by muse, mutect2, varscan2
- DUSP3 | c.354C>T p.G118= | Splice Region (SNP) | VAF 75/281 reads (27%) | called by muse, mutect2, varscan2
- DYNC1I2 | c.1888G>T p.E630* | Nonsense Mutation (SNP) | VAF 32/271 reads (12%) | called by muse, mutect2, varscan2
- EBF1 | c.873A>T p.L291F | Missense Mutation (SNP) | VAF 66/124 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ECEL1 | c.1127T>A p.L376Q | Missense Mutation (SNP) | VAF 130/282 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- EGFR | c.2933dup p.Y978* | Nonsense Mutation (INS) | VAF 62/493 reads (13%) | called by mutect2, pindel, varscan2
- EGR3 | c.697G>T p.A233S | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- EGR3 | c.696G>T p.K232N | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- ELF5 | c.91A>C p.M31L (on ENST00000312319 / NM_198381.2; = p.M21L on NM_001422.4) | Missense Mutation (SNP) | VAF 37/184 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- ELP3 | c.1220G>T p.G407V | Missense Mutation (SNP) | VAF 55/193 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EMILIN2 | c.1367G>C p.R456T | Missense Mutation (SNP) | VAF 64/157 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- EMX1 | c.868G>C p.D290H | Missense Mutation (SNP) | VAF 58/168 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- EPG5 | c.6874A>T p.I2292F | Missense Mutation (SNP) | VAF 236/459 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- EPG5 | c.3400A>T p.S1134C | Missense Mutation (SNP) | VAF 64/122 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- EPHA3 | c.659C>A p.S220Y | Missense Mutation (SNP) | VAF 71/131 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- EPS15 | c.2305C>T p.P769S | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- ERC2 | c.746G>T p.R249L | Missense Mutation (SNP) | VAF 68/131 reads (52%) | SIFT tolerated (0.51); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- ERICH1 | c.1223T>G p.L408R | Missense Mutation (SNP) | VAF 112/338 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ESPNL | c.1882A>T p.T628S | Missense Mutation (SNP) | VAF 183/432 reads (42%) | SIFT tolerated (0.67); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ESX1 | c.337C>A p.P113T | Missense Mutation (SNP) | VAF 149/213 reads (70%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- ETV1 | c.815G>T p.C272F | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- EXOC7 | c.1091A>T p.Y364F (on ENST00000335146 / NM_001145297.4; = p.Y282F on NM_015219.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 109/420 reads (26%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- EYS | c.5520G>C p.W1840C | Missense Mutation (SNP) | VAF 49/288 reads (17%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- EYS | c.3203A>G p.D1068G | Missense Mutation (SNP) | VAF 33/132 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- F2 | c.1252A>T p.T418S | Missense Mutation (SNP) | VAF 92/477 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- FAM114A1 | c.945+1G>T p.X315_splice | Splice Site (SNP) | VAF 16/87 reads (18%) | called by muse, mutect2, varscan2
- FAM135B | c.2452G>T p.D818Y | Missense Mutation (SNP) | VAF 54/154 reads (35%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.204); called by muse, mutect2, varscan2
- FAM240A | c.180G>T p.K60N (on ENST00000444264; = p.K54N on NM_001195442.2) | Missense Mutation (SNP) | VAF 27/145 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- FAM78A | c.385G>T p.G129W | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FANCM | c.4810G>T p.D1604Y | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FASTKD3 | c.1119G>T p.R373S | Missense Mutation (SNP) | VAF 88/447 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAT1 | c.1747G>T p.G583C | Missense Mutation (SNP) | VAF 52/275 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.705); called by muse, mutect2, varscan2
- FAT4 | c.9285C>G p.H3095Q | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FAT4 | c.10204G>T p.D3402Y | Missense Mutation (SNP) | VAF 32/182 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FER | c.2385G>C p.K795N | Missense Mutation (SNP) | VAF 61/143 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- FFAR1 | c.298C>A p.L100M | Missense Mutation (SNP) | VAF 235/373 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- FGD5 | c.2645G>C p.S882T | Missense Mutation (SNP) | VAF 254/418 reads (61%) | SIFT tolerated (0.07); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- FGF23 | c.379T>A p.Y127N | Missense Mutation (SNP) | VAF 129/684 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FIGNL2 | c.1384G>T p.A462S | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.15); called by mutect2, varscan2
- FLG | c.8759A>T p.Q2920L | Missense Mutation (SNP) | VAF 68/1486 reads (5%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2
- FLG | c.8758C>A p.Q2920K | Missense Mutation (SNP) | VAF 69/1508 reads (5%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2
- FLG2 | c.3239G>T p.G1080V | Missense Mutation (SNP) | VAF 180/588 reads (31%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- FLOT2 | c.404G>T p.R135L | Missense Mutation (SNP) | VAF 89/297 reads (30%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- FMO4 | c.541G>C p.G181R | Missense Mutation (SNP) | VAF 48/265 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- FOXD1 | c.627C>G p.F209L | Missense Mutation (SNP) | VAF 161/337 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FOXL2 | c.485C>G p.P162R | Missense Mutation (SNP) | VAF 76/525 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- FOXP2 | c.1352C>A p.T451K | Missense Mutation (SNP) | VAF 122/339 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- FPGT | c.1569G>T p.E523D | Missense Mutation (SNP) | VAF 20/174 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- FRMPD4 | c.3106G>T p.G1036W | Missense Mutation (SNP) | VAF 79/120 reads (66%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- FRY | c.2047G>T p.D683Y | Missense Mutation (SNP) | VAF 92/278 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- FSD2 | c.1708A>T p.K570* | Nonsense Mutation (SNP) | VAF 105/196 reads (54%) | called by muse, mutect2, varscan2
- FSIP2 | c.11223T>A p.N3741K | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- FSIP2 | c.16468C>A p.P5490T | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- FSIP2 | c.17587G>C p.V5863L | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- FSTL5 | c.1842G>T p.R614S | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- FUOM | c.238G>T p.E80* | Nonsense Mutation (SNP) | VAF 27/66 reads (41%) | called by muse, mutect2, varscan2
- GABRA6 | c.134A>T p.N45I | Missense Mutation (SNP) | VAF 108/533 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- GABRR2 | c.304C>A p.L102M | Missense Mutation (SNP) | VAF 109/224 reads (49%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- GCKR | c.1136C>T p.T379I | Missense Mutation (SNP) | VAF 42/367 reads (11%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2, varscan2
- GEN1 | c.2144G>T p.C715F | Missense Mutation (SNP) | VAF 51/219 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GJB5 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 119/608 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GK2 | c.1253C>A p.P418Q | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- GLE1 | c.1025A>T p.E342V | Missense Mutation (SNP) | VAF 109/550 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- GLI1 | c.591dup p.D198* | Frame Shift Ins (INS) | VAF 35/262 reads (13%) | called by mutect2, pindel, varscan2
- GNRHR | c.287C>A p.P96Q | Missense Mutation (SNP) | VAF 154/422 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GOLGB1 | c.7014G>T p.L2338F | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- GP2 | c.971T>G p.L324R (on ENST00000381362 / NM_001007240.3; = p.L321R on NM_001502.4) | Missense Mutation (SNP) | VAF 59/130 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GPR179 | c.5285C>A p.A1762D (on ENST00000621958; = p.A1761D on NM_001004334.4) | Missense Mutation (SNP) | VAF 34/257 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- GRIA4 | c.1751G>T p.G584V | Missense Mutation (SNP) | VAF 29/157 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- GRIN2B | c.2219C>A p.A740E | Missense Mutation (SNP) | VAF 26/171 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- GRM1 | c.3004C>A p.L1002I | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- GRM5 | c.1885T>A p.Y629N | Missense Mutation (SNP) | VAF 71/168 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GRM7 | c.105G>T p.Q35H | Missense Mutation (SNP) | VAF 24/152 reads (16%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- GRM7 | c.976C>A p.H326N | Missense Mutation (SNP) | VAF 44/205 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRM8 | c.320C>G p.S107C | Missense Mutation (SNP) | VAF 90/214 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- GTF3C4 | c.1889A>G p.Q630R | Missense Mutation (SNP) | VAF 48/285 reads (17%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GZMA | c.34C>A p.L12I | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- H2AC6 | c.194A>T p.E65V | Missense Mutation (SNP) | VAF 60/357 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HACE1 | c.715-1G>T p.X239_splice | Splice Site (SNP) | VAF 81/166 reads (49%) | called by muse, mutect2, varscan2
- HAVCR2 | c.501C>A p.S167R | Missense Mutation (SNP) | VAF 50/109 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- HBE1 | c.262A>T p.K88* | Nonsense Mutation (SNP) | VAF 76/438 reads (17%) | called by muse, mutect2, varscan2
- HEATR9 | c.650G>A p.R217Q | Missense Mutation (SNP) | VAF 111/360 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- HELQ | c.1246G>T p.A416S | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- HELZ | c.697G>T p.G233C | Missense Mutation (SNP) | VAF 104/397 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- HERC2 | c.5578G>T p.G1860* | Nonsense Mutation (SNP) | VAF 31/68 reads (46%) | called by muse, mutect2, varscan2
- HEY1 | c.737C>A p.S246Y | Missense Mutation (SNP) | VAF 60/196 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- HGFAC | c.1241C>G p.S414W | Missense Mutation (SNP) | VAF 175/555 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HIBADH | c.713A>T p.K238I | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.389); called by muse, mutect2
- HIVEP2 | c.1147C>A p.P383T | Missense Mutation (SNP) | VAF 80/193 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- HLA-DQA2 | c.26T>G p.L9R | Missense Mutation (SNP) | VAF 140/252 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HMCN2 | c.4988G>T p.G1663V | Missense Mutation (SNP) | VAF 132/369 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HOXA2 | c.391+7C>A | Splice Region (SNP) | VAF 36/185 reads (19%) | called by muse, mutect2, varscan2
- IFITM3 | c.50C>A p.P17H | Missense Mutation (SNP) | VAF 44/226 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); called by muse, varscan2
- IGFBP2 | c.265G>T p.V89L | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.335); called by muse, mutect2, varscan2
- IGKV2D-24 | c.7C>A p.L3I | Missense Mutation (SNP) | VAF 87/354 reads (25%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.498); called by muse, mutect2, varscan2
- IGKV3D-7 | c.91C>A p.P31T | Missense Mutation (SNP) | VAF 24/390 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2
- IGSF9B | c.4147G>C p.V1383L | Missense Mutation (SNP) | VAF 98/268 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- IK | c.1136A>G p.K379R | Missense Mutation (SNP) | VAF 180/276 reads (65%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- INHBA | c.1144A>T p.S382C | Missense Mutation (SNP) | VAF 44/120 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- INVS | c.2132G>T p.S711I | Missense Mutation (SNP) | VAF 80/143 reads (56%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- IRS4 | c.2308T>A p.S770T | Missense Mutation (SNP) | VAF 140/231 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- IRX2 | c.250G>T p.G84C | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- IRX4 | c.83A>C p.E28A | Missense Mutation (SNP) | VAF 64/304 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.681); called by muse, mutect2, varscan2
- IRX4 | c.82G>T p.E28* | Nonsense Mutation (SNP) | VAF 62/301 reads (21%) | called by muse, mutect2, varscan2
- ITGB8 | c.477G>A p.M159I | Missense Mutation (SNP) | VAF 21/146 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- ITIH5 | c.1191C>G p.S397R | Missense Mutation (SNP) | VAF 145/462 reads (31%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- ITIH6 | c.505del p.Q169Nfs*3 | Frame Shift Del (DEL) | VAF 164/317 reads (52%) | called by mutect2, pindel, varscan2
- ITPRID1 | c.1439G>A p.R480K | Missense Mutation (SNP) | VAF 92/313 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- JCAD | c.2327C>A p.T776K | Missense Mutation (SNP) | VAF 132/437 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.1525G>T p.A509S | Missense Mutation (SNP) | VAF 82/153 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- JSRP1 | c.955G>T p.G319W | Missense Mutation (SNP) | VAF 38/65 reads (58%) | SIFT deleterious (0.03); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- KANK1 | c.1296G>T p.E432D | Missense Mutation (SNP) | VAF 104/195 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- KAT6A | c.1545del p.K516Sfs*29 | Frame Shift Del (DEL) | VAF 108/406 reads (27%) | called by mutect2, pindel, varscan2
- KCNN4 | c.1022A>T p.Q341L | Missense Mutation (SNP) | VAF 114/179 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); called by muse, mutect2, varscan2
- KIAA0232 | c.3865G>T p.E1289* | Nonsense Mutation (SNP) | VAF 12/152 reads (8%) | called by muse, mutect2
- KIAA1841 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 41/138 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- KIF13B | c.4001C>A p.A1334D | Missense Mutation (SNP) | VAF 64/265 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- KIF5C | c.1705G>T p.D569Y | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- KLF8 | c.839G>C p.G280A | Missense Mutation (SNP) | VAF 41/77 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KLHL31 | c.86A>T p.K29I | Missense Mutation (SNP) | VAF 56/169 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- KLHL33 | c.750G>T p.W250C | Missense Mutation (SNP) | VAF 66/278 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KLHL5 | c.1834G>T p.A612S | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.859); called by muse, mutect2
- KLK13 | c.689G>T p.G230V | Missense Mutation (SNP) | VAF 88/184 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KRTAP19-8 | c.106G>T p.G36C | Missense Mutation (SNP) | VAF 125/345 reads (36%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KY | c.1352C>A p.P451H | Missense Mutation (SNP) | VAF 126/234 reads (54%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LAMA1 | c.438C>A p.F146L | Missense Mutation (SNP) | VAF 146/498 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- LAMA4 | c.4900A>T p.T1634S (on ENST00000230538 / NM_001105206.3; = p.T1627S on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 129/289 reads (45%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- LAMA5 | c.7418A>C p.Q2473P | Missense Mutation (SNP) | VAF 45/130 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- LOXL3 | c.1415A>T p.Q472L | Missense Mutation (SNP) | VAF 102/305 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); called by muse, mutect2, varscan2
- LPO | c.1810C>T p.P604S | Missense Mutation (SNP) | VAF 29/282 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- LRFN5 | c.575C>A p.S192Y | Missense Mutation (SNP) | VAF 51/148 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- LRFN5 | c.652C>G p.R218G | Missense Mutation (SNP) | VAF 80/265 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- LRGUK | c.1459G>T p.G487C | Missense Mutation (SNP) | VAF 47/113 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- LRIT3 | c.1062dup p.P355Tfs*5 | Frame Shift Ins (INS) | VAF 13/69 reads (19%) | called by mutect2, pindel, varscan2
- LRP2 | c.6682C>A p.L2228I | Missense Mutation (SNP) | VAF 78/209 reads (37%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRPPRC | c.2719G>T p.A907S | Missense Mutation (SNP) | VAF 19/308 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); called by muse, mutect2
- LRRC18 | c.544C>A p.P182T | Missense Mutation (SNP) | VAF 36/175 reads (21%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRRC4C | c.1319C>T p.T440I | Missense Mutation (SNP) | VAF 38/193 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- LRRC4C | c.28C>A p.Q10K | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRRC66 | c.1492G>C p.G498R | Missense Mutation (SNP) | VAF 85/287 reads (30%) | SIFT tolerated (0.47); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- LRRC7 | c.21G>T p.R7S | Missense Mutation (SNP) | VAF 32/178 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- LRRC71 | c.1012C>A p.H338N | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LRRC74B | c.241G>T p.A81S | Missense Mutation (SNP) | VAF 107/286 reads (37%) | SIFT tolerated (0.71); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- LRRC8A | c.1101C>G p.D367E | Missense Mutation (SNP) | VAF 48/286 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LYSMD1 | c.303A>T p.E101D | Missense Mutation (SNP) | VAF 65/439 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LYSMD1 | c.302A>T p.E101V | Missense Mutation (SNP) | VAF 64/435 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.353); called by muse, mutect2, varscan2
- LYST | c.3451G>T p.V1151L | Missense Mutation (SNP) | VAF 37/186 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- MACF1 | c.4993G>T p.G1665C | Missense Mutation (SNP) | VAF 73/124 reads (59%) | called by muse, mutect2, varscan2
- MAIP1 | c.784A>T p.S262C | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); called by muse, mutect2
- MAIP1 | c.785G>T p.S262I | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.013); called by muse, mutect2
- MAN1C1 | c.1849del p.V617* | Frame Shift Del (DEL) | VAF 63/160 reads (39%) | called by mutect2, pindel, varscan2
- MBD5 | c.2845+1G>C p.X949_splice | Splice Site (SNP) | VAF 79/203 reads (39%) | called by muse, mutect2, varscan2
- MDH1 | c.989T>C p.F330S | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.539); called by muse, mutect2, varscan2
- MDN1 | c.8014+1G>T p.X2672_splice | Splice Site (SNP) | VAF 14/86 reads (16%) | called by muse, mutect2
- METTL17 | c.1184G>T p.R395L | Missense Mutation (SNP) | VAF 107/346 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MFRP | c.137G>T p.G46V (on ENST00000449574; = p.G422V on NM_031433.4) | Missense Mutation (SNP) | VAF 73/200 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- MFSD4B | c.68_69dup p.P24Sfs*23 (on ENST00000368847; = p.A119Efs*22 on NM_153369.4) | Frame Shift Ins (INS) | VAF 17/87 reads (20%) | called by mutect2, pindel
- MGAM2 | c.4717C>A p.L1573I | Missense Mutation (SNP) | VAF 41/120 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- MICAL2 | c.622G>A p.D208N | Missense Mutation (SNP) | VAF 54/161 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- MICU1 | c.605G>T p.G202V (on ENST00000361114 / NM_001195518.2; = p.G208V on NM_006077.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MKI67 | c.1145G>T p.G382V | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- MMP9 | c.1881C>A p.F627L | Missense Mutation (SNP) | VAF 90/262 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.666); called by muse, mutect2, varscan2
- MN1 | c.901C>A p.Q301K | Missense Mutation (SNP) | VAF 52/169 reads (31%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.056); called by muse, varscan2
- MPPED2 | c.558G>T p.W186C | Missense Mutation (SNP) | VAF 51/165 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- MRC1 | c.2045C>A p.A682D | Missense Mutation (SNP) | VAF 78/272 reads (29%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.619); called by muse, mutect2, varscan2
- MRC1 | c.2669C>A p.P890H | Missense Mutation (SNP) | VAF 163/621 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- MRPL13 | c.231C>G p.Y77* | Nonsense Mutation (SNP) | VAF 29/93 reads (31%) | called by muse, mutect2, varscan2
- MTIF2 | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 134/435 reads (31%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MTUS1 | c.1893_1895dup p.A632dup | In Frame Ins (INS) | VAF 34/289 reads (12%) | called by mutect2, pindel, varscan2
- MUC12 | c.3227A>T p.Q1076L (on ENST00000379442; = p.Q933L on NM_001164462.1) | Missense Mutation (SNP) | VAF 174/301 reads (58%) | SIFT deleterious (0.02); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- MUC16 | c.22901G>T p.S7634I | Missense Mutation (SNP) | VAF 67/186 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- MUC2 | c.1031C>A p.T344N | Missense Mutation (SNP) | VAF 44/284 reads (15%) | SIFT tolerated (0.12); called by muse, mutect2, varscan2
- MUC22 | c.4373C>G p.A1458G | Missense Mutation (SNP) | VAF 80/476 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- MUC5AC | c.880G>T p.D294Y | Missense Mutation (SNP) | VAF 76/471 reads (16%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- MUC5B | c.11141C>G p.S3714C | Missense Mutation (SNP) | VAF 137/448 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MUCL1 | c.13C>G p.H5D | Missense Mutation (SNP) | VAF 66/213 reads (31%) | called by muse, mutect2, varscan2
- MYCBPAP | c.1361A>T p.Y454F | Missense Mutation (SNP) | VAF 52/243 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- MYH1 | c.3109G>T p.D1037Y | Missense Mutation (SNP) | VAF 195/317 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- MYH13 | c.4168C>A p.L1390M | Missense Mutation (SNP) | VAF 170/276 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYH2 | c.1729G>T p.E577* | Nonsense Mutation (SNP) | VAF 171/300 reads (57%) | called by muse, mutect2, varscan2
- MYH3 | c.3636dup p.R1213Afs*19 | Frame Shift Ins (INS) | VAF 209/495 reads (42%) | called by mutect2, pindel, varscan2
- MYLK | c.1942+4T>A | Splice Region (SNP) | VAF 201/445 reads (45%) | called by muse, mutect2, varscan2
- MYO1B | c.929G>C p.C310S | Missense Mutation (SNP) | VAF 66/190 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- MYO1D | c.480C>G p.S160R | Missense Mutation (SNP) | VAF 40/318 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYO1G | c.2966G>T p.R989L | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- MYOF | c.874+1G>T p.X292_splice | Splice Site (SNP) | VAF 30/91 reads (33%) | called by muse, mutect2, varscan2
- MYOG | c.597C>A p.H199Q | Missense Mutation (SNP) | VAF 75/161 reads (47%) | SIFT tolerated (0.28); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- MYOZ1 | c.504A>G p.G168= | Splice Region (SNP) | VAF 61/240 reads (25%) | called by muse, mutect2, varscan2
- MYT1 | c.3238-1G>T p.X1080_splice | Splice Site (SNP) | VAF 62/130 reads (48%) | called by muse, mutect2, varscan2
- NALCN | c.601G>A p.G201R | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NAV2 | c.283G>T p.A95S | Missense Mutation (SNP) | VAF 71/187 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NBEA | c.3008T>A p.I1003K | Missense Mutation (SNP) | VAF 59/201 reads (29%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- NBPF12 | c.2210A>C p.E737A | Missense Mutation (SNP) | VAF 82/433 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- NCKAP5 | c.5047C>A p.L1683M | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- NCKAP5L | c.2027A>T p.E676V | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- NDST4 | c.1499G>T p.R500I | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.094); called by muse, mutect2
- NDUFAF6 | c.112_114del p.G38del | In Frame Del (DEL) | VAF 34/354 reads (10%) | called by mutect2, pindel
- NDUFS8 | c.292G>T p.E98* | Nonsense Mutation (SNP) | VAF 45/310 reads (15%) | called by muse, mutect2, varscan2
- NEB | c.7802G>A p.S2601N | Missense Mutation (SNP) | VAF 194/707 reads (27%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.547); called by muse, mutect2, varscan2
- NEK10 | c.2552C>A p.A851D | Missense Mutation (SNP) | VAF 72/97 reads (74%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- NELL1 | c.1261G>T p.G421C | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NELL1 | c.1262G>T p.G421V | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NELL1 | c.1838G>T p.C613F | Missense Mutation (SNP) | VAF 47/273 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NEUROD1 | c.752del p.A251Efs*11 | Frame Shift Del (DEL) | VAF 151/564 reads (27%) | called by mutect2, pindel, varscan2
- NFASC | c.904C>G p.R302G (on ENST00000339876 / NM_001378329.1; = p.R313G on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/122 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- NFIC | c.89C>T p.T30I | Missense Mutation (SNP) | VAF 97/182 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NFIC | c.457A>C p.K153Q | Missense Mutation (SNP) | VAF 132/309 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NGF | c.683C>G p.A228G | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- NKD2 | c.220A>T p.K74* | Nonsense Mutation (SNP) | VAF 40/275 reads (15%) | called by muse, mutect2, varscan2
- NKX2-5 | c.824C>A p.P275H | Missense Mutation (SNP) | VAF 60/115 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- NLGN1 | c.788G>T p.G263V | Missense Mutation (SNP) | VAF 52/321 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NME8 | c.297G>T p.Q99H | Missense Mutation (SNP) | VAF 102/263 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- NOG | c.527G>T p.G176V | Missense Mutation (SNP) | VAF 45/152 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NOS2 | c.575A>T p.Q192L | Missense Mutation (SNP) | VAF 99/345 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- NPTX1 | c.686A>C p.Q229P | Missense Mutation (SNP) | VAF 82/311 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- NPY5R | c.512G>T p.C171F | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- NRXN3 | c.1791G>T p.E597D (on ENST00000335750 / NM_001330195.2; = p.E224D on NM_004796.6) | Missense Mutation (SNP) | VAF 134/302 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- NSMF | c.620_626del p.R207Lfs*49 (on ENST00000371475 / NM_001130969.3; = p.R207Lfs*47 on NM_015537.4) | Frame Shift Del (DEL) | VAF 73/557 reads (13%) | called by mutect2, pindel, varscan2
- NTSR1 | c.628C>G p.Q210E | Missense Mutation (SNP) | VAF 35/175 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- OR10AG1 | c.271C>A p.Q91K | Missense Mutation (SNP) | VAF 58/130 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- OR10AG1 | c.120A>G p.I40M | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- OR10J1 | c.570C>A p.D190E | Missense Mutation (SNP) | VAF 85/284 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- OR10V1 | c.701G>T p.G234V | Missense Mutation (SNP) | VAF 42/123 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR13C3 | c.331A>T p.T111S | Missense Mutation (SNP) | VAF 117/377 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- OR13D1 | c.935T>C p.V312A | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- OR1N2 | c.68G>C p.W23S | Missense Mutation (SNP) | VAF 52/182 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2
- OR2D2 | c.608G>T p.G203V | Missense Mutation (SNP) | VAF 24/151 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR2T6 | c.464A>T p.D155V | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- OR4C11 | c.501T>A p.C167* | Nonsense Mutation (SNP) | VAF 35/236 reads (15%) | called by muse, mutect2, varscan2
- OR4K17 | c.686C>T p.S229F | Missense Mutation (SNP) | VAF 72/297 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.464); called by muse, mutect2, varscan2
- OR4N2 | c.822C>A p.F274L | Missense Mutation (SNP) | VAF 59/896 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.174); called by muse, mutect2
- OR4S2 | c.845C>A p.P282H | Missense Mutation (SNP) | VAF 50/144 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR51G2 | c.260T>A p.L87Q | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- OR51M1 | c.274dup p.T92Nfs*9 | Frame Shift Ins (INS) | VAF 32/217 reads (15%) | called by mutect2, pindel, varscan2
- OR51Q1 | c.302C>T p.A101V | Missense Mutation (SNP) | VAF 89/265 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- OR6C1 | c.416G>T p.C139F | Missense Mutation (SNP) | VAF 106/305 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR6N1 | c.24G>C p.Q8H | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR6P1 | c.43G>T p.V15L | Missense Mutation (SNP) | VAF 64/236 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- OR9I1 | c.437T>A p.V146E | Missense Mutation (SNP) | VAF 68/166 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- OR9K2 | c.364dup p.C122Lfs*15 (on ENST00000305377; = p.C100Lfs*15 on NM_001005243.1) | Frame Shift Ins (INS) | VAF 73/268 reads (27%) | called by mutect2, pindel, varscan2
- P2RY14 | c.585C>A p.F195L | Missense Mutation (SNP) | VAF 187/350 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PALLD | c.1714A>T p.S572C | Missense Mutation (SNP) | VAF 73/352 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.594); called by muse, mutect2, varscan2
- PAQR5 | c.446A>T p.H149L | Missense Mutation (SNP) | VAF 125/237 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- PATL2 | c.927G>C p.E309D | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- PAWR | c.166G>T p.G56W | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- PCDHB15 | c.1555C>A p.L519M | Missense Mutation (SNP) | VAF 355/665 reads (53%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- PCDHB3 | c.812C>A p.T271K | Missense Mutation (SNP) | VAF 90/166 reads (54%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- PCLO | c.5686A>G p.T1896A | Missense Mutation (SNP) | VAF 32/136 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- PDCD11 | c.3369-1G>T p.X1123_splice | Splice Site (SNP) | VAF 44/161 reads (27%) | called by muse, mutect2, varscan2
- PDCD4 | c.403G>T p.E135* | Nonsense Mutation (SNP) | VAF 34/217 reads (16%) | called by muse, mutect2, varscan2
- PDE1C | c.185C>A p.T62K | Missense Mutation (SNP) | VAF 29/177 reads (16%) | SIFT tolerated, low confidence (0.31); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- PDE5A | c.1166A>T p.E389V | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- PDZRN4 | c.571del p.R191Gfs*37 | Frame Shift Del (DEL) | VAF 50/245 reads (20%) | called by mutect2, pindel, varscan2
- PEAR1 | c.143G>T p.S48I | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- PEG3 | c.88G>T p.E30* | Nonsense Mutation (SNP) | VAF 92/143 reads (64%) | called by muse, mutect2, varscan2
- PEX16 | c.389G>T p.W130L | Missense Mutation (SNP) | VAF 88/253 reads (35%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.699); called by muse, mutect2, varscan2
- PFAS | c.101A>T p.Q34L | Missense Mutation (SNP) | VAF 51/116 reads (44%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- PGK2 | c.112C>A p.Q38K | Missense Mutation (SNP) | VAF 36/227 reads (16%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- PIK3R2 | c.1956_1957insT p.G653Wfs*158 | Frame Shift Ins (INS) | VAF 42/100 reads (42%) | called by mutect2, pindel, varscan2
- PITRM1 | c.16G>C p.G6R | Missense Mutation (SNP) | VAF 68/209 reads (33%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PKD2 | c.2136G>T p.L712F | Missense Mutation (SNP) | VAF 49/308 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- PLA2G1B | c.215A>C p.N72T | Missense Mutation (SNP) | VAF 20/170 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- PLB1 | c.980A>G p.H327R | Missense Mutation (SNP) | VAF 49/213 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PLCB1 | c.2473A>T p.K825* | Nonsense Mutation (SNP) | VAF 90/271 reads (33%) | called by muse, mutect2, varscan2
- PLCE1 | c.1809+1G>T p.X603_splice | Splice Site (SNP) | VAF 64/218 reads (29%) | called by muse, mutect2, varscan2
- PLCL1 | c.470del p.K157Sfs*7 | Frame Shift Del (DEL) | VAF 62/212 reads (29%) | called by mutect2, pindel, varscan2
- PLCL1 | c.1911G>T p.K637N | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- PLEC | c.10216G>T p.E3406* (on ENST00000322810 / NM_201380.4; = p.E3296* on NM_000445.5) | Nonsense Mutation (SNP) | VAF 140/878 reads (16%) | called by muse, mutect2, varscan2
- PLEKHA5 | c.266C>T p.T89I | Missense Mutation (SNP) | VAF 59/191 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- PLEKHH2 | c.1453C>G p.Q485E | Missense Mutation (SNP) | VAF 75/222 reads (34%) | SIFT tolerated (0.42); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- PLEKHO2 | c.217G>T p.D73Y | Missense Mutation (SNP) | VAF 53/316 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PLOD1 | c.1711G>T p.E571* | Nonsense Mutation (SNP) | VAF 105/225 reads (47%) | called by muse, mutect2, varscan2
- PLOD3 | c.833G>T p.G278V | Missense Mutation (SNP) | VAF 49/200 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLSCR2 | c.125A>T p.Y42F | Missense Mutation (SNP) | VAF 57/358 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- POTEE | c.296G>T p.G99V | Missense Mutation (SNP) | VAF 116/680 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); called by muse, varscan2
- POU4F2 | c.403C>A p.P135T | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- POU4F2 | c.637G>T p.V213L | Missense Mutation (SNP) | VAF 58/146 reads (40%) | SIFT tolerated (0.36); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PPP1R9A | c.2833A>T p.K945* | Nonsense Mutation (SNP) | VAF 42/253 reads (17%) | called by muse, mutect2, varscan2
- PPRC1 | c.4756G>T p.V1586F | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRELID1 | c.586_588dup p.A196dup | In Frame Ins (INS) | VAF 40/322 reads (12%) | called by mutect2, pindel, varscan2
- PRF1 | c.1147C>T p.P383S | Missense Mutation (SNP) | VAF 65/294 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- PRG4 | c.3677_3703del p.A1226_K1234del | In Frame Del (DEL) | VAF 66/425 reads (16%) | called by mutect2, pindel
- PRKCSH | c.1249_1258dup p.T420Rfs*50 | Frame Shift Ins (INS) | VAF 48/156 reads (31%) | called by mutect2, varscan2
- PRKN | c.604C>A p.P202T | Missense Mutation (SNP) | VAF 108/254 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- PRLR | c.1461C>A p.D487E | Missense Mutation (SNP) | VAF 159/334 reads (48%) | SIFT tolerated (0.32); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PROM2 | c.2483G>T p.R828L | Missense Mutation (SNP) | VAF 86/320 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PRRC2A | c.1846G>T p.V616L | Missense Mutation (SNP) | VAF 30/194 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRSS1 | c.114G>T p.Q38H | Missense Mutation (SNP) | VAF 62/552 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- PTBP2 | c.1390A>C p.T464P (on ENST00000426398 / NM_001300986.2; = p.T456P on NM_021190.4) | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PTCD1 | c.1283C>T p.A428V | Missense Mutation (SNP) | VAF 35/145 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PTCHD3 | c.392G>T p.G131V | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.657); called by muse, mutect2, varscan2
- PTCHD4 | c.2236C>G p.Q746E | Missense Mutation (SNP) | VAF 92/284 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PTGIS | c.446T>A p.L149* | Nonsense Mutation (SNP) | VAF 40/154 reads (26%) | called by muse, mutect2, varscan2
- PTPN12 | c.284A>T p.K95M | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- PTPRA | c.1822G>A p.G608S | Missense Mutation (SNP) | VAF 66/215 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PTPRB | c.3832G>C p.A1278P | Missense Mutation (SNP) | VAF 68/183 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- PTPRB | c.2612C>A p.T871N | Missense Mutation (SNP) | VAF 58/291 reads (20%) | SIFT tolerated (0.49); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- PTPRH | c.2410G>A p.D804N | Missense Mutation (SNP) | VAF 160/276 reads (58%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- PTPRM | c.4094T>C p.L1365S | Missense Mutation (SNP) | VAF 81/265 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PTPRN | c.2041G>T p.E681* | Nonsense Mutation (SNP) | VAF 32/244 reads (13%) | called by muse, mutect2
- PTPRZ1 | c.3377A>T p.Q1126L | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- PURG | c.655G>T p.E219* | Nonsense Mutation (SNP) | VAF 72/274 reads (26%) | called by muse, mutect2, varscan2
- PXYLP1 | c.1093G>T p.E365* | Nonsense Mutation (SNP) | VAF 45/210 reads (21%) | called by muse, mutect2, varscan2
- RAD51AP2 | c.79G>T p.D27Y | Missense Mutation (SNP) | VAF 90/257 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- RADIL | c.368G>T p.G123V | Missense Mutation (SNP) | VAF 35/168 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- RASSF4 | c.760A>T p.R254W | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- RASSF9 | c.763C>T p.Q255* | Nonsense Mutation (SNP) | VAF 54/137 reads (39%) | called by muse, mutect2, varscan2
- RECQL4 | c.2980G>C p.D994H | Missense Mutation (SNP) | VAF 57/182 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- RERE | c.4578G>T p.E1526D | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RESP18 | c.274C>A p.Q92K | Missense Mutation (SNP) | VAF 60/191 reads (31%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- RGS21 | c.147G>T p.E49D | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RICTOR | c.2114T>C p.L705S | Missense Mutation (SNP) | VAF 98/240 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RIMS2 | c.776A>T p.Y259F (on ENST00000666250 / NM_001348490.2; = p.Y67F on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/122 reads (32%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- RNF150 | c.1139A>G p.Q380R | Missense Mutation (SNP) | VAF 47/266 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- RNF207 | c.1706A>G p.D569G | Missense Mutation (SNP) | VAF 45/315 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- RNPC3 | c.4G>T p.A2S | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- RREB1 | c.3038A>T p.Q1013L | Missense Mutation (SNP) | VAF 54/147 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- RSPH14 | c.343T>C p.F115L | Missense Mutation (SNP) | VAF 68/202 reads (34%) | SIFT tolerated (0.79); PolyPhen benign (0.003); called by mutect2, varscan2
- RTN4 | c.1082C>T p.S361F | Missense Mutation (SNP) | VAF 48/163 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SAMHD1 | c.1270G>T p.D424Y | Missense Mutation (SNP) | VAF 103/356 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SAP18 | c.115C>A p.R39S (on ENST00000607003; = p.R58S on NM_005870.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 99/205 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- SCFD2 | c.1228G>T p.G410* | Nonsense Mutation (SNP) | VAF 52/280 reads (19%) | called by muse, mutect2, varscan2
- SCN7A | c.3000G>T p.W1000C | Missense Mutation (SNP) | VAF 26/298 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SCNN1A | c.1403A>C p.H468P | Missense Mutation (SNP) | VAF 165/473 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SEC24C | c.2009A>C p.K670T | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- SELENOW | c.153G>T p.M51I | Missense Mutation (SNP) | VAF 143/284 reads (50%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- SERPINB11 | c.647A>G p.Y216C | Missense Mutation (SNP) | VAF 61/121 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SERPINC1 | c.34G>T p.G12* | Nonsense Mutation (SNP) | VAF 54/292 reads (18%) | called by muse, mutect2, varscan2
- SF3A1 | c.2237A>T p.E746V | Missense Mutation (SNP) | VAF 76/236 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- SH2D4B | c.528A>T p.E176D | Missense Mutation (SNP) | VAF 56/195 reads (29%) | SIFT tolerated (0.62); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- SH3BP5L | c.1087C>G p.L363V | Missense Mutation (SNP) | VAF 62/129 reads (48%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SIGLEC1 | c.4061del p.F1354Sfs*11 | Frame Shift Del (DEL) | VAF 44/172 reads (26%) | called by mutect2, pindel
- SIGLECL1 | c.251G>T p.C84F | Missense Mutation (SNP) | VAF 132/206 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SIX5 | c.1997C>G p.S666* | Nonsense Mutation (SNP) | VAF 206/556 reads (37%) | called by muse, mutect2, varscan2
- SLC16A7 | c.56G>T p.G19V | Missense Mutation (SNP) | VAF 37/223 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC25A16 | c.61_69del p.Q21_A23del | In Frame Del (DEL) | VAF 36/147 reads (24%) | called by mutect2, pindel, varscan2
- SLC25A26 | c.442G>T p.V148F | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- SLC26A9 | c.621C>A p.F207L | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- SLC27A2 | c.1458-2A>T p.X486_splice | Splice Site (SNP) | VAF 49/97 reads (51%) | called by muse, mutect2, varscan2
- SLC35E4 | c.224G>T p.G75V | Missense Mutation (SNP) | VAF 64/183 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- SLC35F3 | c.694G>T p.V232F (on ENST00000366617 / NM_001300845.1; = p.V301F on NM_173508.4) | Missense Mutation (SNP) | VAF 64/122 reads (52%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- SLC4A1 | c.1081G>T p.G361C | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SLC4A1 | c.490G>T p.A164S | Missense Mutation (SNP) | VAF 167/594 reads (28%) | SIFT tolerated (0.46); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- SLC4A3 | c.3061G>T p.G1021C | Missense Mutation (SNP) | VAF 98/276 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC5A6 | c.459+1G>T p.X153_splice | Splice Site (SNP) | VAF 66/215 reads (31%) | called by muse, mutect2, varscan2
- SLC5A6 | c.459G>T p.M153I | Missense Mutation (SNP) | VAF 66/221 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- SLC6A12 | c.690G>T p.K230N | Missense Mutation (SNP) | VAF 58/172 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- SLC6A13 | c.1582T>A p.W528R | Missense Mutation (SNP) | VAF 56/182 reads (31%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- SLC6A13 | c.1459A>T p.R487W | Missense Mutation (SNP) | VAF 54/168 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SLC6A5 | c.877T>G p.Y293D | Missense Mutation (SNP) | VAF 83/236 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SMAD6 | c.629G>C p.R210P | Missense Mutation (SNP) | VAF 65/102 reads (64%) | SIFT tolerated (0.15); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- SMARCA4 | c.4750G>T p.E1584* | Nonsense Mutation (SNP) | VAF 92/189 reads (49%) | called by muse, mutect2, varscan2
- SMC3 | c.2572G>T p.V858F | Missense Mutation (SNP) | VAF 43/192 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- SMG9 | c.549G>T p.L183F | Missense Mutation (SNP) | VAF 120/197 reads (61%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- SNAI1 | c.229C>T p.L77F | Missense Mutation (SNP) | VAF 80/264 reads (30%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- SNCB | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 206/311 reads (66%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- SNORC | c.49G>T p.V17F | Missense Mutation (SNP) | VAF 61/404 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- SOWAHB | c.2341A>G p.K781E | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SPATA31A1 | c.3752G>T p.R1251M | Missense Mutation (SNP) | VAF 202/555 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- SPEF2 | c.3378G>C p.E1126D | Missense Mutation (SNP) | VAF 184/381 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.567); called by muse, mutect2, varscan2
- SPPL2C | c.1565T>A p.L522H | Missense Mutation (SNP) | VAF 87/284 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SPRR2A | c.134G>T p.C45F | Missense Mutation (SNP) | VAF 33/176 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.539); called by muse, mutect2, varscan2
- SPTA1 | c.1094A>G p.K365R | Missense Mutation (SNP) | VAF 31/257 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- SPTBN1 | c.3093G>T p.Q1031H | Missense Mutation (SNP) | VAF 81/281 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
463 further variants in this file (100 protein-altering or splice-affecting, 236 silent, 127 other) are not listed here.
